Surgical pathology report (de-identified scan), TCGA case TCGA-98-8023, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-8023-01A (Primary Tumor).

[page 1 of 3]
Patient Name MR# Observation Date Last Edited Date

SURGICAL PATHOLOGY CASE: Received Date:

Diagnosis: Report is corrected on to correct typographical errors in lymph node designations. The content of the diagnoses is unchanged.

- A. Lymph node, level VII, lymph node, excision:- One lymph node negative for malignancy (0/1).
- B. Lymph node, level VIII, lymph node, excision:- One lymph node negative for malignancy (0/1).
- C. Lymph node, level VIII lymph node #2, excision:- Benign lymph node exhibiting focal dystrophic calcification.
- One lymph node negative for malignancy (0/1).
- D. Soft tissue, level IX, lymph node, excision:- Benign fibrovascular connective tissue.- No lymph node identified.- Negative for malignancy.
- E. Lymph node, level X, lymph node, excision:- Benign fibroadipose tissue and peripheral nerve.
- Negative for malignancy.
- F. Lymph node, 4-R, excision:- One lymph node negative for malignancy (0/1).
- G. Lung, right main stem tissue, biopsy:- Benign lymph node and adjacent fibrovascular connective tissue.
- Negative for malignancy.
- H. Lung, tracheal material, biopsy:- Benign fibroadipose tissue with cartilage.- Negative for malignancy.
- I. Lymph node, level XIII, lymph node, excision:- One lymph node negative for malignancy (0/1).
- Lymph node with calcified granuloma.
- J. Lymph node, level X, excision:- Metastatic squamous I carcinoma.
- K. Lymph node, level XII, lymph node, excision:- One lymph node negative for malignancy (0/1).
- L. Lymph node, level XI, excision:- One lymph node negative for malignancy (0/1).- Lymph node with calcified granuloma.
- M. Lymph node, level VII, lymph node, excision: - One lymph node negative for malignancy (0/1).
- N. Lung, bronchial margin, excision: - Negative for malignancy.
- O. Lung, right upper lobectomy and right middle lobectomy:- Invasive squamous cell carcinoma, moderately to poorly differentiated.- Tumor measures 10.0 cm in maximal dimension.- Pleura uninvolved by tumor.

Pathologist Comments: Immunoperoxidase stains for p63 and TTF-1 are performed. Tumor cells are reactive for p63 and are non-reactive for TTF-1 consistent with a poorly differentiated squamous cell carcinoma. Controls are appropriately reactive.

[page 2 of 3]
Clinical Information: This is a [REDACTED] year-old male with a lung mass.

Frozen Section Diagnosis

AFS1- Lymph node level VII lymph node, excision:- Benign lymph node tissue.- Negative for malignancy.

BFS1- Lymph node level VIII lymph node, excision:- Benign lymph node tissue.- Negative for malignancy.

CFS1- Lymph node level VIII lymph node #2, excision:- Benign lymph node tissue exhibiting focal dystrophic calcification.- Negative for malignancy.

DFS1- Soft tissue level IX lymph node FS, excision:- Benign fibrovascular connective tissue.
- Negative for malignancy. FFS1- Lymph node, IV-R, excision: - Benign lymph node tissue.
- Negative for malignancy.

GFS1- Right main stem tissue, biopsy:- Benign lymph node and adjacent fibrovascular connective tissue.
- Negative for malignancy.

HFS1- Tracheal material biopsy: - Benign portion of lymph node tissue and adjacent connective tissue.
- Negative for malignancy.

JFS1- Lymph node, level X, excision: - Metastatic non small cell carcinoma.

NFS1- Bronchial margin, excision:- Bronchial tissue, negative for malignancy.

OFS1- Right lung, right upper lobectomy and right middle lobectomy:- Non small cell carcinoma, 10 x 7 x 4 cm. [REDACTED]

Gross Description: The specimen is received in fifteen containers all labeled with the patients name, and medical record number. The first container is received in formalin and labeled "level VII lymph node." Received are multiple fragments of gray-tan tissue that measure in aggregate 3.8 x 2.4 x 0.3 cm; and entirely submitted. The second container is received in formalin and labeled "level VIII lymph node." Received in formalin is the frozen cassette. Per frozen section paper are multiple fragments of gray-tan tissue that measure 3.8 x 2.0 x 1.8 cm in aggregate; and entirely submitted. The third container is labeled "level VIII lymph node #2 frozen section." Received is a 2.0 x 1.2 x 0.8 cm anthracotic appearing nodule with calcified center measuring 1.2 x 0.7 x 0.5 cm. The fourth container is labeled "level IV lymph node." Received is a frozen cassette and tissue. Per frozen section paperwork, received is yellow adipose tissue and fibrosed tissue that measures 1.0 x 0.6 x 0.5 cm, and entirely submitted. The fifth container is labeled "level X lymph node." Received is dark tan tissue that measures 1.0 x 0.7 x 0.5 cm. The sixth container is labeled "level IV-R lymph node." Received is a frozen cassette and tissue. Per frozen section paperwork, received is a 1.5 x 2.5 x 1.2 cm aggregate of gray tan tissue. The seventh container is labeled "right main stem tissue." Received is a frozen cassette and tissue. Per frozen form, received are two pieces of tan yellow tissue each measuring 0.6 cm. The eighth container is labeled "tracheal material." Per frozen section paperwork, received is a 0.6 x 0.5 x 0.4 cm piece of tan tissue. The ninth container is labeled "level XIII lymph node." Received are two dark tan fragments of tissue, the largest fragment measuring 0.7 x 0.5 x 0.4 cm. The smaller fragment measures 0.6 x 0.2 x 0.3 cm. The tenth container is labeled "level X-R lymph node." Received is a frozen cassette and tissue. Per frozen section form, received is a 2.0 x 1.5 x 1.7 cm tan yellow cut surface. The eleventh container is labeled "level XII lymph node." Received are two fragments of tan tissue. The larger fragment measures 1.5 x 1.0 x 0.5 cm. The smaller fragment measures 1.2 x 0.7 x 0.4 cm. The twelfth container is labeled "level XI lymph node." Received is a fragment of black and tan tissue that measures 0.8 x 0.5 x 0.4 cm. The thirteenth container is labeled "level VII lymph node." Received is a tan and brown fragment of tissue that measures 1.2 x 0.7 x 0.5 cm. The fourteenth container is labeled "bronchial margin." Received is a frozen cassette and tissue within. Per frozen section form, received is 0.9 x 0.6 x 0.4 cm piece of curled rubbery tissue, that is entirely submitted after removal of staples. The fifteenth container is labeled "right upper lobe and right middle lobe." Received is a frozen cassette and tissue which consists of tan piece of tissue that measures 1.4 x 1.0 x 0.4 cm, as well as the upper and middle right lobe. Per frozen section form, received is a 10 x 7 x 4 cm tumor and a 20 x 13 x 5 cm, right upper lobe lobectomy by right middle lobectomy (surface defect of 7 x 6 cm) where tumor was cut

[page 3 of 3]
prior to receipt in frozen section room. The external surface will be inked green. A stapled margin is noted. Sectioning reveals significant transudate versus exudate. Material is tan colored foamy fluid. The 10 cm tumor appears to encase the bronchioles and comes to within 1 mm of the visceral pleura but does not protrude through. No other foci are noted. [REDACTED]

Block Summary

- A1- Frozen section level VII lymph node
- B1- Level VIII lymph node entirely submitted
- C1- Frozen section tissue level VIII lymph node
- C2- Remainder of tissue level VIII lymph node
- D1- Frozen section level IX lymph node entirely submitted
- E1- Level X lymph node entirely submitted and bisected
- F1- Frozen section level IV-R lymph node entirely submitted
- G1- Right main stem tissue frozen section entirely submitted
- H1- Frozen section tracheal material entirely submitted
- I1- Level XIII lymph node - final entirely submitted
- J1- Frozen section of level X-R lymph node entirely submitted
- K1- Level XII lymph node - both the smaller and larger fragments have been bisected, entirely submitted
- L1- Level XI lymph node bisected and entirely submitted
- M1- Level VII lymph node bisected and entirely submitted
- N1- Frozen section of bronchial margin entirely submitted
- O1- Frozen section from upper and middle lobe
- O2-04 Sections through tumor at visceral pleural margin
- 05-07 Representative sections through tumor
- 08-09 Representative sections of normal lung parenchyma

Microscopic Description: A microscopic examination has been performed [REDACTED]

SP Synoptic Report O: Thorax Lung

SPECIMEN: Lobe(s) of lung: right upper and middle

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Upper lobe. Middle lobe

TUMOR SIZE: Greatest dimension: 10 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: G3: Poorly differentiated

VISCERAL PLEURA INVASION: Not identified

BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION: Present

LYMPH NODES: Present

PRIMARY TUMOR (pT): pT3: Tumor > 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor in the main bronchus < 2 cm distal to the carina but w/o involvement of the carina; or Tumor with atelectasis or obstructive pneumonitis of the entire lung; or Tumors with separate tumor nodule(s) in same lobe

REGIONAL LYMPH NODES (pN): pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including involvement by direct extension

[REDACTED]

Source: NCI Genomic Data Commons file e09809fe-01dc-4db4-b401-2e9740735df5 (TCGA-98-8023.F1BFBAFB-5CF1-414E-B14F-989573D4CBED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).